Somatic mutation profile of tumor specimen 0DWBCG from CCDI case PBCNRC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 0.4 years (131 days).
Specimen 0DWBCG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ca9ce1d-7a46-4e49-9b0b-c3bff3e2cb9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWBCO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97c273d7-b020-43a3-8958-f1baae244650

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 3, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTN3 | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 40/359 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs764619298, COSV55167035; called by muse, mutect2, varscan2
- ADAM32 | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 126/444 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.236); called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 42/724 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 26/554 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- GOLGA8K | c.648G>A p.E216= | Silent (SNP) | VAF 45/400 reads (11%) | called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 26/254 reads (10%) | called by muse, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 5/46 reads (11%) | called by muse, varscan2
- TTC8 | c.459+44T>A | Intron (SNP) | VAF 20/193 reads (10%) | called by muse, varscan2
- TUBGCP4 | c.1066-64C>T | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, varscan2
